Gene-level copy-number profile of tumor specimen C3L-05905-58 from CPTAC case C3L-05905, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 32.1 years (11,729 days).
Specimen C3L-05905-58: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7208e1b3-adbc-42af-aab3-b5ac5a6089df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05905-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/6adc3762-db26-4c84-9bba-0f1a9a32369b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 60; copy number 2: 58,328; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–73,865, 5 genes (within-gene range 0–2): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:46,549,044–46,652,025, 8 genes, copy number 5: GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P.

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
